Gene-level copy-number profile of tumor specimen TCGA-77-8008-01A from TCGA case TCGA-77-8008, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 68.3 years (24,948 days).
Specimen TCGA-77-8008-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.89693321-ff43-47e8-b123-33520355abd6.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-77-8008-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 388 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/9e3e01cc-f445-4925-95e4-9433cf55c262

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 2,518; copy number 1: 1,613; copy number 2: 8,769; copy number 3: 15,935; copy number 4: 21,863; copy number 5: 5,437; copy number 6: 2,807; copy number 7: 143; copy number 8: 997; copy number 9: 78; copy number 19: 26; copy number 26: 18; copy number 35: 4; copy number 56: 27.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-77-8008-01A-21D-2183-01): tumor purity 0.27, ploidy 2, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 131 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:85,934,535–85,937,548, 1 gene: AC012511.2.
- chr9:558,826–558,930, 1 gene: RNU6-1327P.
- chr12:23,108,458–23,108,493, 1 gene: AC087258.1.
- chr15:19,878,555–22,225,329, 126 genes (broad region; genes not listed).
- chr17:41,271,311–41,271,835, 1 gene: KRTAP9-11P.
- chr17:65,654,914–65,655,395, 1 gene: AC004805.2.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 153 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:32,517,353–32,589,848, 4 genes, copy number 35: HLA-DRB5, RNU1-61P, HLA-DRB6, HLA-DRB1.
- chr8:37,784,191–40,520,158, 71 genes, copy number 19–56 (within-gene range 7–56) (broad region; genes not listed).
- chr13:106,773,623–106,774,279, 1 gene, copy number 9: AL162574.2.
- chr20:87,250–2,641,784, 77 genes, copy number 9 (within-gene range 6–9) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,082. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
